Somatic mutation profile of tumor specimen TCGA-J4-A83M-01A (aliquot TCGA-J4-A83M-01A-11D-A34U-08) from TCGA case TCGA-J4-A83M, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,624 days).
Specimen TCGA-J4-A83M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6980a2d-316e-4855-8dcf-c145015d7422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A83M-10A (Blood Derived Normal), aliquot TCGA-J4-A83M-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab999a36-b691-4679-ba14-60c2ac593d74

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 5/57 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62572120, COSV62572141; called by muse, mutect2
- ABHD6 | c.980T>G p.V327G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.091); catalogued as COSV99916976; called by muse, mutect2, varscan2
- ADAMTS12 | c.1090T>A p.S364T | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100710579; called by muse, mutect2, varscan2
- CCDC146 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs770508290, COSV53548067; called by muse, mutect2, varscan2
- CCL11 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs56358892, COSV59924967; called by muse, mutect2, varscan2
- CTSE | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs199778962, COSV63061312; called by muse, mutect2
- IFI16 | c.1239T>A p.Y413* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99857303; called by mutect2, varscan2
- MACF1 | c.15395G>T p.R5132L (on ENST00000372915; = p.R3065L on NM_012090.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV57141642, COSV99242976; called by muse, mutect2, varscan2
- MED15 | c.1409+2T>A p.X470_splice (on ENST00000263205 / NM_001003891.3; = p.X430_splice on NM_015889.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99487547; called by muse, mutect2
- MEGF6 | c.2009G>A p.S670N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV99619889; called by muse, mutect2
- OR10G8 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.157); catalogued as COSV101461820; called by muse, mutect2, varscan2
- PALB2 | c.3037A>G p.I1013V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1567212950, COSV99848260; ClinVar: uncertain significance; called by muse, mutect2
- PAMR1 | c.245A>T p.H82L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99552384; called by muse, mutect2, varscan2
- PCLO | c.9688C>T p.R3230C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs372228421, COSV100440293; called by muse, mutect2, varscan2
- PDE1C | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs775258741, COSV100371920; called by muse, mutect2
- PLXNC1 | c.2393C>A p.S798Y | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as COSV99312797; called by muse, mutect2
- SLC6A9 | c.1901G>A p.R634H (on ENST00000360584 / NM_201649.4; = p.R580H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs780357551, COSV100746123; called by muse, mutect2, varscan2
- TP53INP1 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs201012799; called by muse, mutect2, varscan2
- TSG101 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99323833; called by muse, mutect2, varscan2
- UBR4 | c.6598C>T p.Q2200* | Nonsense Mutation (SNP) | VAF 28/99 reads (28%) | catalogued as rs267598259, COSV100920645; called by muse, mutect2, varscan2
- ZEB1 | c.2795A>G p.H932R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100314042; called by muse, mutect2
- ZNF689 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); catalogued as COSV99787922; called by muse, mutect2, varscan2
- CYP4V2 | c.571dup p.Y191Lfs*12 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | called by mutect2, varscan2
- ACACA | c.4965T>A p.T1655= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- DNAH17 | c.4035G>A p.T1345= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs539639486, COSV101101866; called by muse, mutect2, varscan2
- DUS3L | c.291A>G p.L97= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1226633416, COSV100288051; called by muse, mutect2, varscan2
- EMSY | c.3543T>C p.T1181= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs779584974, COSV100595574; called by muse, mutect2, varscan2
- F7 | c.831C>T p.D277= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs745921084, COSV60647898; called by muse, mutect2, varscan2
- MUC15 | c.450T>C p.T150= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs1288563931, COSV55554097, COSV99846312; called by muse, mutect2, varscan2
- PLPPR4 | c.1911G>A p.P637= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs201385642, COSV100926892, COSV64567674; called by muse, mutect2, varscan2
